Somatic mutation profile of tumor specimen TCGA-D9-A6E9-06A (aliquot TCGA-D9-A6E9-06A-12D-A30X-08) from TCGA case TCGA-D9-A6E9, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 75.4 years (27,537 days).
Specimen TCGA-D9-A6E9-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 30b45c8c-8c1d-4c09-bccd-1830aa081b42.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D9-A6E9-10A (Blood Derived Normal), aliquot TCGA-D9-A6E9-10A-01D-A30X-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/76cd67a1-6f3f-46a2-b7e3-e7ffed7258ae

The open-access MAF lists 199 somatic variants for this specimen: 145 protein-altering or splice-affecting, 48 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 128, Silent 48, Splice Region 6, Nonsense Mutation 6, RNA 4, Splice Site 4, Intron 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- A2M | c.2395C>T p.P799S | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59387622; called by muse, mutect2, varscan2
- ABCA13 | c.9406G>A p.E3136K | Missense Mutation (SNP) | VAF 38/206 reads (18%) | SIFT tolerated (0.69); PolyPhen benign (0.019); catalogued as COSV71289134; called by muse, mutect2, varscan2
- ACOT8 | c.56C>T p.P19L | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs200293125, COSV54169790; called by muse, mutect2, varscan2
- ARHGAP36 | c.208G>A p.E70K | Missense Mutation (SNP) | VAF 51/167 reads (31%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.935); catalogued as COSV52264412; called by muse, mutect2, varscan2
- ASCC3 | c.4250C>T p.S1417F | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.56); catalogued as COSV64975847; called by muse, mutect2, varscan2
- ASNSD1 | c.1651C>T p.P551S | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53623847; called by muse, mutect2
- ATP8A2 | c.3344G>A p.G1115E | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.42); PolyPhen benign (0.261); catalogued as COSV54955302; called by muse, mutect2, varscan2
- AXDND1 | c.2115G>A p.M705I | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV62642676; called by muse, mutect2, varscan2
- BPTF | c.2899C>T p.R967* | Nonsense Mutation (SNP) | VAF 24/153 reads (16%) | catalogued as COSV58838240; called by muse, mutect2, varscan2
- BTBD3 | c.62C>T p.T21M | Missense Mutation (SNP) | VAF 22/249 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.412); catalogued as rs776639503, COSV54778795; called by muse, mutect2
- BTBD7 | c.2168C>T p.P723L | Missense Mutation (SNP) | VAF 19/133 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58286553; called by muse, mutect2, varscan2
- C5 | c.1793C>T p.S598F | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56328110; called by muse, mutect2, varscan2
- CAPRIN2 | c.754G>A p.D252N | Missense Mutation (SNP) | VAF 17/134 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.6); catalogued as COSV51832955; called by muse, mutect2, varscan2
- CCDC180 | c.3223C>T p.Q1075* | Nonsense Mutation (SNP) | VAF 16/48 reads (33%) | catalogued as COSV63831023; called by muse, mutect2, varscan2
- CDC40 | c.603T>G p.D201E | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.421); catalogued as COSV57009925; called by muse, mutect2, varscan2
- CDH20 | c.268G>A p.G90R | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53010915; called by muse, mutect2, varscan2
- CEP43 | c.649C>T p.L217F | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.467); catalogued as rs768130325, COSV62760975; called by muse, mutect2, varscan2
- CNDP1 | c.556G>A p.D186N | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.584); catalogued as COSV62593546; called by muse, mutect2
- COL14A1 | c.1601C>T p.A534V | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV52856295, COSV52857181; called by muse, mutect2
- COL2A1 | c.3007G>A p.E1003K | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.956); catalogued as rs376772481; called by muse, mutect2, varscan2
- COL4A4 | c.1525G>T p.G509W | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61632798; called by muse, mutect2, varscan2
- COL4A5 | c.188G>A p.G63E | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV60362950; called by muse, varscan2
- COL6A3 | c.4978C>T p.R1660C | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.663); catalogued as rs1553556695, COSV55092173; ClinVar: uncertain significance; called by muse, mutect2
- COL6A3 | c.3613G>A p.V1205M | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.921); catalogued as COSV55092185; called by muse, mutect2, varscan2
- COL6A5 | c.6646G>T p.G2216W (on ENST00000312481; = p.G2212W on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.792); catalogued as COSV55204230; called by muse, mutect2, varscan2
- COQ6 | c.1095G>A p.G365= | Splice Region (SNP) | VAF 8/40 reads (20%) | catalogued as COSV53178927; called by muse, mutect2, varscan2
- CPT1A | c.1157G>A p.G386E | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.402); catalogued as COSV55756782; called by muse, mutect2, varscan2
- CPZ | c.268G>A p.E90K (on ENST00000360986 / NM_001014447.3; = p.E79K on NM_003652.3) | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.33); PolyPhen benign (0.018); catalogued as rs761264809, COSV59923379; called by muse, mutect2, varscan2
- CSMD1 | c.3044G>A p.G1015E (on ENST00000520002; = p.G1014E on NM_033225.6) | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747056562, COSV59332126; called by muse, mutect2
- CTNNB1 | c.1170T>G p.D390E | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV62702262; called by muse, mutect2, varscan2
- CYTL1 | c.239C>T p.S80L | Missense Mutation (SNP) | VAF 33/139 reads (24%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.458); catalogued as rs771311426, COSV57036975; called by muse, mutect2, varscan2
- DCAF8L1 | c.1389C>G p.F463L | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV71595329, COSV71595333; called by muse, mutect2, varscan2
- DMBT1 | c.5989A>T p.T1997S (on ENST00000338354 / NM_001377530.1; = p.T1240S on NM_004406.3) | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.31); PolyPhen benign (0.234); catalogued as COSV57545897; called by muse, mutect2, varscan2
- DNAH5 | c.8522C>T p.T2841I | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV54207821; called by muse, mutect2, varscan2
- DSG3 | c.2825C>T p.S942F | Missense Mutation (SNP) | VAF 27/110 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs141527621, COSV57126777; called by muse, mutect2, varscan2
- EPB41L1 | c.1930G>A p.D644N | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.288); catalogued as rs774491669, COSV52438611; called by muse, mutect2, varscan2
- EPS8L2 | c.1062C>T p.I354= | Splice Region (SNP) | VAF 8/45 reads (18%) | catalogued as rs751072821, COSV59348115; called by muse, mutect2, varscan2
- FBXL7 | c.314C>T p.S105F | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.205); catalogued as COSV61647016; called by muse, mutect2
- FCN3 | c.394G>A p.V132M | Missense Mutation (SNP) | VAF 9/99 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54641538; called by muse, mutect2
- FRMD4A | c.1615G>A p.A539T | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated (0.42); PolyPhen benign (0.135); catalogued as COSV52724910; called by muse, mutect2, varscan2
- FYTTD1 | c.824C>T p.P275L | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54083993; called by muse, mutect2, varscan2
- GALNT5 | c.1234G>A p.A412T | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV52038152, COSV99375564; called by muse, mutect2, varscan2
- GALNT6 | c.1091C>T p.S364F | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.663); catalogued as COSV62542386; called by muse, mutect2, varscan2
- GGT5 | c.1466G>A p.G489E | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54070493; called by muse, mutect2, varscan2
- GHRHR | c.885G>A p.V295= | Splice Region (SNP) | VAF 16/50 reads (32%) | catalogued as rs146944568, COSV58196743; called by muse, mutect2, varscan2
- GPC1 | c.1621C>T p.L541F | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV50863678; called by muse, mutect2, varscan2
- GPD1 | c.193C>T p.P65S | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56548169; called by muse, mutect2, varscan2
- GPR101 | c.1441G>A p.E481K | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.326); catalogued as rs775052562, COSV53239042; called by muse, mutect2, varscan2
- GPR37L1 | c.1192G>A p.G398S | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT tolerated (0.82); PolyPhen benign (0.023); catalogued as rs752647896, COSV66162371; called by muse, mutect2, varscan2
- GRIN3A | c.1261G>A p.E421K | Missense Mutation (SNP) | VAF 38/94 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV100701480, COSV62452322; called by muse, mutect2, varscan2
- GUCY2D | c.1136C>G p.A379G | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT tolerated (0.58); PolyPhen benign (0.09); catalogued as rs1460624299, COSV54696555; called by muse, mutect2, varscan2
- IGSF1 | c.2446G>A p.E816K | Missense Mutation (SNP) | VAF 102/315 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as COSV63837868; called by muse, mutect2, varscan2
- IGSF9 | c.2548G>A p.D850N (on ENST00000368094 / NM_001135050.2; = p.D834N on NM_020789.4) | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.417); catalogued as rs1165931283, COSV57422438; called by muse, mutect2
- IL1RAPL2 | c.544G>A p.E182K | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.992); catalogued as COSV100781819, COSV61149662; called by muse, mutect2, varscan2
- INSRR | c.2947C>T p.R983W | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs190741064, COSV63873874; called by muse, mutect2, varscan2
- KCNH5 | c.2323A>G p.K775E | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.018); catalogued as COSV59762109; called by muse, mutect2, varscan2
- KIAA0232 | c.1715G>A p.S572N | Missense Mutation (SNP) | VAF 35/160 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.018); catalogued as COSV56925791; called by muse, mutect2, varscan2
- KIZ | c.1772C>T p.S591L | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV55684137; called by muse, mutect2
- KLRK1 | c.462G>A p.W154* | Nonsense Mutation (SNP) | VAF 20/97 reads (21%) | catalogued as COSV53698627, COSV53698734; called by muse, mutect2, varscan2
- LILRB4 | c.1300G>A p.G434R (on ENST00000391733 / NM_001278428.3; = p.G433R on NM_001278426.3) | Missense Mutation (SNP) | VAF 16/144 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs765132717, COSV99553592, COSV99553933; called by muse, mutect2
- LRP2 | c.6562A>G p.T2188A | Missense Mutation (SNP) | VAF 32/132 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.053); catalogued as COSV55556364; called by muse, mutect2, varscan2
- LTBP1 | c.3236-1G>A p.X1079_splice (on ENST00000404816 / NM_206943.4; = p.X753_splice on NM_000627.4) | Splice Site (SNP) | VAF 18/72 reads (25%) | catalogued as COSV55379985; called by muse, mutect2, varscan2
- LUM | c.905C>T p.S302F | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.022); catalogued as COSV57128320, COSV57129047; called by muse, mutect2
- MAGEC1 | c.850T>C p.F284L | Missense Mutation (SNP) | VAF 46/148 reads (31%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.113); catalogued as COSV53573871; called by muse, varscan2
- MAP2 | c.5347C>T p.P1783S | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52293104; called by muse, mutect2, varscan2
- MIA2 | c.1609C>T p.P537S | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.444); catalogued as COSV54488126, COSV54494219; called by muse, mutect2, varscan2
- MRPS11 | c.187T>A p.Y63N | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.185); catalogued as COSV100363821, COSV57915107; called by muse, mutect2, varscan2
- MTMR3 | c.2344C>T p.P782S | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); catalogued as COSV60309286; called by muse, mutect2, varscan2
- MUC17 | c.186T>C p.G62= | Splice Region (SNP) | VAF 17/68 reads (25%) | catalogued as COSV60290519; called by muse, mutect2
- MXRA5 | c.2762C>T p.S921F | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.259); catalogued as COSV54237620; called by muse, mutect2, varscan2
- MYH10 | c.3410C>T p.A1137V | Missense Mutation (SNP) | VAF 22/124 reads (18%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.461); catalogued as COSV52602683; called by muse, mutect2, varscan2
- MYH6 | c.1715G>A p.G572E | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.977); catalogued as rs1422951029, COSV62451344; called by muse, mutect2, varscan2
- MYO3B | c.835G>A p.E279K | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58704822; called by muse, mutect2, varscan2
- NCOA6 | c.1295C>T p.P432L | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV62864291; called by muse, mutect2, varscan2
- NEB | c.6829G>A p.E2277K | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.992); catalogued as rs1384095848, COSV51422297; called by muse, mutect2, varscan2
- NFIC | c.437C>T p.T146I | Missense Mutation (SNP) | VAF 66/185 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1490524764, COSV59413041; called by muse, mutect2, varscan2
- NLRP12 | c.2326G>A p.D776N | Missense Mutation (SNP) | VAF 41/138 reads (30%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); catalogued as rs1003800314, COSV60748524; called by muse, mutect2, varscan2
- NLRP8 | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT tolerated (0.29); PolyPhen benign (0.039); catalogued as COSV52583981; called by muse, mutect2, varscan2
- NMNAT2 | c.379G>A p.G127R | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.922); catalogued as rs200836216, COSV54268853; called by muse, mutect2, varscan2
- OR1F1 | c.548C>T p.P183L | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.168); catalogued as COSV58961249; called by muse, mutect2, varscan2
- OR2A12 | c.905G>A p.R302K | Missense Mutation (SNP) | VAF 53/248 reads (21%) | SIFT tolerated (0.34); PolyPhen benign (0.02); catalogued as COSV68821132, COSV68822139; called by muse, mutect2, varscan2
- OR7G2 | c.517A>G p.S173G | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as COSV59688125; called by muse, mutect2, varscan2
- P2RY4 | c.1000T>A p.S334T | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as COSV65736732; called by muse, mutect2, varscan2
- PDGFB | c.457-1G>A p.X153_splice | Splice Site (SNP) | VAF 19/67 reads (28%) | catalogued as COSV58647576; called by muse, mutect2, varscan2
- PKHD1 | c.12104G>A p.S4035N | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.007); catalogued as COSV64391468; called by muse, mutect2
- PLEKHG4B | c.3127G>A p.V1043I (on ENST00000283426; = p.V1399I on NM_052909.5) | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs376759485; called by muse, mutect2, varscan2
- PMEL | c.871G>A p.V291I | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as COSV59386334; called by muse, mutect2
- PNCK | c.884C>T p.T295I (on ENST00000340888 / NM_001366975.1; = p.T378I on NM_001039582.3) | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.05); catalogued as rs1557039431, COSV61744105; called by muse, mutect2
- PPDPFL | c.140C>T p.P47L | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.043); catalogued as COSV57461325, COSV57462499; called by muse, mutect2, varscan2
- PPP1R13L | c.2250C>T p.D750= | Splice Region (SNP) | VAF 6/33 reads (18%) | catalogued as rs1235757811, COSV62908654; called by muse, mutect2, varscan2
- PPP1R16B | c.1394C>T p.A465V | Missense Mutation (SNP) | VAF 29/121 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs770210301, COSV55378477; called by muse, mutect2, varscan2
- PPP1R3A | c.1390G>A p.G464R | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.486); catalogued as rs1433400825, COSV52884028; called by muse, mutect2, varscan2
- PRM1 | c.8G>A p.R3K | Missense Mutation (SNP) | VAF 17/90 reads (19%) | PolyPhen probably damaging (0.992); catalogued as COSV54113297; called by muse, mutect2, varscan2
- PTCHD3 | c.880C>T p.P294S | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT tolerated (0.55); PolyPhen benign (0.009); catalogued as COSV71256892; called by muse, mutect2, varscan2
- RFWD3 | c.482C>T p.A161V | Missense Mutation (SNP) | VAF 37/104 reads (36%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.001); catalogued as COSV63097940; called by muse, mutect2, varscan2
- RP1L1 | c.2291G>A p.G764E | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as COSV66755918; called by muse, mutect2, varscan2
- SCN11A | c.4931C>T p.S1644F | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.325); catalogued as COSV56571451; called by muse, mutect2, varscan2
- SCNN1D | c.457G>A p.E153K (on ENST00000338555; = p.E317K on NM_001130413.4) | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.069); catalogued as rs760711177, COSV57641818; called by muse, mutect2, varscan2
- SEC24A | c.653C>A p.P218Q | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.549); catalogued as COSV59747569; called by muse, mutect2, varscan2
- SH3GL1 | c.710C>T p.A237V | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.62); PolyPhen benign (0.244); catalogued as rs571418230, COSV53657718; called by muse, mutect2
- SHROOM4 | c.1463G>A p.G488E | Missense Mutation (SNP) | VAF 42/127 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56790320; called by muse, mutect2, varscan2
- SLC12A2 | c.823T>C p.Y275H | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV52471951; called by muse, mutect2, varscan2
- SLC17A6 | c.1528G>A p.E510K | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (0.28); PolyPhen benign (0.066); catalogued as COSV54137048; called by muse, mutect2, varscan2
- SLC1A2 | c.310+2T>G p.X104_splice | Splice Site (SNP) | VAF 12/69 reads (17%) | catalogued as COSV53522021; called by muse, mutect2, varscan2
- SLC25A12 | c.1230T>G p.N410K | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV55533908; called by muse, mutect2, varscan2
- SLC38A1 | c.97G>A p.E33K | Missense Mutation (SNP) | VAF 41/112 reads (37%) | SIFT tolerated (0.27); PolyPhen benign (0.028); catalogued as rs75571325, COSV67063416; called by muse, mutect2, varscan2
- SLC4A1 | c.696C>T p.G232= | Splice Region (SNP) | VAF 5/27 reads (19%) | catalogued as rs748181631, COSV52260490; called by muse, mutect2
- SLC5A11 | c.829G>A p.G277R | Missense Mutation (SNP) | VAF 53/166 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100762892, COSV61741940; called by muse, mutect2, varscan2
- SLC7A13 | c.89G>A p.G30E | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867805359, COSV52534817, COSV99879296; called by muse, mutect2, varscan2
- SNAP91 | c.2357A>G p.E786G | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1485913975, COSV99534696; called by muse, mutect2
- SNCAIP | c.1042G>A p.E348K | Missense Mutation (SNP) | VAF 30/141 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.385); catalogued as rs534709742, COSV54401767; called by muse, mutect2, varscan2
- SPATS2L | c.916A>G p.M306V | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as COSV62348717; called by muse, mutect2, varscan2
- SPON2 | c.268G>A p.V90I | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.56); catalogued as rs1023369767, COSV52054669, COSV52054859; called by muse, mutect2, varscan2
- SRPRA | c.118G>A p.E40K | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.988); catalogued as COSV55007017; called by muse, varscan2
- SSX3 | c.550G>A p.E184K | Missense Mutation (SNP) | VAF 41/284 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.917); catalogued as COSV53644236; called by muse, mutect2, varscan2
- STC2 | c.233T>C p.I78T | Missense Mutation (SNP) | VAF 111/362 reads (31%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.996); catalogued as COSV54180185; called by muse, mutect2, varscan2
- STK26 | c.609G>A p.W203* | Nonsense Mutation (SNP) | VAF 12/32 reads (38%) | catalogued as COSV61230015; called by muse, mutect2, varscan2
- STMN2 | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.991); catalogued as COSV55219865; called by muse, mutect2, varscan2
- STRN4 | c.995C>A p.P332Q | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated (0.55); PolyPhen benign (0.077); catalogued as COSV54418859; called by muse, mutect2, varscan2
- TACC2 | c.1450G>T p.G484W | Missense Mutation (SNP) | VAF 40/118 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV57757519; called by muse, mutect2, varscan2
- TBC1D32 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.206); catalogued as rs771929833, COSV51544693; called by muse, mutect2, varscan2
- TIMM10B | c.136-1G>A p.X46_splice | Splice Site (SNP) | VAF 33/151 reads (22%) | catalogued as COSV99601446; called by muse, mutect2, varscan2
- TIMM10B | c.136G>A p.E46K | Missense Mutation (SNP) | VAF 33/152 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); catalogued as COSV99601447; called by muse, mutect2, varscan2
- TLR1 | c.1376G>A p.S459N | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.012); catalogued as rs745699566, COSV58304548; called by muse, mutect2, varscan2
- TMEM230 | c.79G>A p.D27N | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.767); catalogued as rs761361465, COSV52532424; called by muse, mutect2, varscan2
- TMPRSS11E | c.281C>T p.S94F | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV59519458; called by muse, mutect2, varscan2
- TNN | c.2090G>A p.S697N | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs781194887, COSV53427432; called by muse, mutect2, varscan2
- TPO | c.62C>T p.P21L | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.084); catalogued as rs868461747, COSV61103057; called by muse, mutect2, varscan2
- TRAPPC3 | c.331C>T p.P111S | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64264403; called by muse, mutect2, varscan2
- UBE4B | c.872C>T p.P291L | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.054); catalogued as rs199643842, COSV53533663; called by muse, mutect2, varscan2
- UNC13C | c.1309C>T p.P437S | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as COSV52879895; called by muse, mutect2, varscan2
- USP11 | c.1786G>T p.E596* (on ENST00000218348; = p.E553* on NM_001371072.1) | Nonsense Mutation (SNP) | VAF 16/66 reads (24%) | catalogued as COSV54473950; called by muse, mutect2, varscan2
- UVRAG | c.584C>T p.S195F | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV62104921; called by muse, mutect2, varscan2
- VPS13D | c.7324C>T p.P2442S | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.99); catalogued as COSV50643739; called by muse, mutect2, varscan2
- XIRP2 | c.6400C>T p.P2134S (on ENST00000628543; = p.P2309S on NM_152381.6) | Missense Mutation (SNP) | VAF 19/101 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.412); catalogued as COSV54704251; called by muse, mutect2, varscan2
- YBX3 | c.520C>T p.R174W | Missense Mutation (SNP) | VAF 42/141 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs748937054, COSV54385494; called by muse, mutect2, varscan2
- ZDBF2 | c.682C>T p.L228F | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as COSV65626695; called by muse, mutect2, varscan2
- ZKSCAN2 | c.664C>T p.P222S | Missense Mutation (SNP) | VAF 19/159 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV60157204; called by muse, mutect2, varscan2
- ZNF566 | c.133A>G p.M45V | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.009); catalogued as rs754927876, COSV67573898; called by muse, mutect2, varscan2
- ZNF609 | c.88G>T p.G30* | Nonsense Mutation (SNP) | VAF 32/125 reads (26%) | catalogued as COSV58584003; called by muse, mutect2, varscan2
- ZSCAN4 | c.1175G>A p.G392E | Missense Mutation (SNP) | VAF 19/210 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56592699, COSV56593272; called by muse, mutect2
- CDK17 | c.222_223del p.H74Qfs*25 | Frame Shift Del (DEL) | VAF 4/24 reads (17%) | called by pindel, varscan2
- NCKAP5 | c.1168G>A p.E390K | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); called by muse, mutect2
- TRAV8-2 | c.83G>A p.S28N | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- AC006059.2 | c.1551C>A p.G517= | Silent (SNP) | VAF 78/214 reads (36%) | catalogued as COSV100045907, COSV59607216; called by muse, mutect2, varscan2
- ADCY8 | c.1755C>T p.Y585= | Silent (SNP) | VAF 31/101 reads (31%) | catalogued as COSV53910539; called by muse, mutect2, varscan2
- ADGRB1 | c.4068G>A p.R1356= | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as rs1457103688, COSV60097553; called by muse, mutect2
- ANKRD30A | c.2784C>T p.L928= (on ENST00000611781; = p.L872= on NM_052997.2) | Silent (SNP) | VAF 14/54 reads (26%) | catalogued as COSV64611868; called by muse, mutect2, varscan2
- ANO4 | c.1812G>A p.L604= (on ENST00000392977 / NM_001286615.2; = p.L569= on NM_178826.4) | Silent (SNP) | VAF 6/94 reads (6%) | catalogued as COSV100151625, COSV54597848; called by muse, mutect2
- ATP2B1 | c.3660C>G p.L1220= | Silent (SNP) | VAF 11/90 reads (12%) | catalogued as COSV53808242; called by muse, mutect2, varscan2
- C14orf39 | c.1023G>A p.T341= | Silent (SNP) | VAF 4/21 reads (19%) | catalogued as rs147156617, COSV58781189; called by muse, mutect2
- CAPN11 | c.1716C>T p.F572= | Silent (SNP) | VAF 12/83 reads (14%) | catalogued as rs1231050712, COSV67237797; called by muse, mutect2, varscan2
- CCDC185 | c.483C>T p.F161= | Silent (SNP) | VAF 5/29 reads (17%) | catalogued as COSV64820420; called by muse, mutect2
- CD8B | c.384G>A p.K128= | Silent (SNP) | VAF 43/182 reads (24%) | catalogued as COSV58926305; called by muse, mutect2, varscan2
- CFAP43 | c.471G>A p.V157= | Silent (SNP) | VAF 33/69 reads (48%) | catalogued as COSV53378268; called by muse, mutect2, varscan2
- CLCN5 | c.1875C>T p.S625= | Silent (SNP) | VAF 11/27 reads (41%) | catalogued as COSV56584447; called by muse, mutect2, varscan2
- CNGA2 | c.1101C>T p.I367= | Silent (SNP) | VAF 21/115 reads (18%) | catalogued as rs141471697, COSV61704820; called by muse, mutect2, varscan2
- COL20A1 | c.477C>T p.S159= | Silent (SNP) | VAF 9/48 reads (19%) | catalogued as rs1283224829, COSV58918393; called by muse, mutect2, varscan2
- EP400 | c.2505C>T p.A835= | Silent (SNP) | VAF 15/81 reads (19%) | catalogued as COSV57774183; called by muse, mutect2, varscan2
- FAM83C | c.1827C>T p.P609= | Silent (SNP) | VAF 21/83 reads (25%) | catalogued as COSV65583238; called by muse, mutect2, varscan2
- FBF1 | c.2355G>A p.E785= (on ENST00000586717; = p.E799= on NM_001319193.1) | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as COSV59865386; called by muse, mutect2, varscan2
- FRRS1 | c.384C>T p.V128= | Silent (SNP) | VAF 6/50 reads (12%) | catalogued as COSV54922454; called by muse, mutect2, varscan2
- HOXB3 | c.570G>A p.R190= | Silent (SNP) | VAF 28/80 reads (35%) | catalogued as rs1375735042, COSV57486766, COSV57487049; called by muse, mutect2, varscan2
- KCNV1 | c.1351C>T p.L451= | Silent (SNP) | VAF 9/39 reads (23%) | catalogued as COSV52086469, COSV52088848; called by muse, mutect2, varscan2
- KLHL1 | c.2241A>G p.Q747= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as COSV64773590; called by muse, mutect2, varscan2
- LACTB2 | c.168C>T p.I56= | Silent (SNP) | VAF 18/63 reads (29%) | catalogued as COSV52568045; called by muse, mutect2, varscan2
- LAMC1 | c.2355C>T p.P785= | Silent (SNP) | VAF 23/124 reads (19%) | catalogued as COSV51145888; called by muse, mutect2, varscan2
- LGI3 | c.186G>T p.L62= | Silent (SNP) | VAF 9/28 reads (32%) | catalogued as COSV60443585; called by muse, mutect2, varscan2
- LILRB4 | c.1299A>G p.E433= (on ENST00000391733 / NM_001278428.3; = p.E432= on NM_001278426.3) | Silent (SNP) | VAF 16/146 reads (11%) | catalogued as rs771375743, COSV99553591; called by muse, mutect2
- MTMR3 | c.2343C>T p.V781= | Silent (SNP) | VAF 14/91 reads (15%) | catalogued as rs758932706, COSV100070564; called by muse, mutect2, varscan2
- MUC16 | c.25650G>A p.P8550= | Silent (SNP) | VAF 23/55 reads (42%) | catalogued as rs370796218, COSV67470509; called by muse, mutect2, varscan2
- MYOC | c.996G>A p.G332= | Silent (SNP) | VAF 22/79 reads (28%) | catalogued as COSV50675258; called by muse, mutect2, varscan2
- MYOF | c.5835C>T p.S1945= | Silent (SNP) | VAF 124/349 reads (36%) | catalogued as rs1564609712, COSV63705107; called by muse, mutect2, varscan2
- NAALADL1 | c.999G>A p.V333= | Silent (SNP) | VAF 21/52 reads (40%) | catalogued as rs775724980, COSV60524232; called by muse, mutect2, varscan2
- NEURL4 | c.4071C>T p.F1357= | Silent (SNP) | VAF 21/96 reads (22%) | catalogued as COSV59750165; called by muse, mutect2, varscan2
- NOP58 | c.1314C>T p.T438= | Silent (SNP) | VAF 18/75 reads (24%) | catalogued as COSV51896889; called by muse, mutect2, varscan2
- OR6C75 | c.12C>T p.S4= | Silent (SNP) | VAF 31/105 reads (30%) | catalogued as COSV58552402; called by muse, mutect2, varscan2
- PCDHB7 | c.351C>T p.F117= | Silent (SNP) | VAF 18/76 reads (24%) | catalogued as COSV50773810; called by muse, mutect2
- PHF12 | c.798C>T p.L266= | Silent (SNP) | VAF 14/81 reads (17%) | catalogued as rs148610349; called by muse, mutect2, varscan2
- PHKB | c.2580C>T p.I860= | Silent (SNP) | VAF 12/94 reads (13%) | catalogued as COSV54523107; called by muse, mutect2, varscan2
- PRAM1 | c.1323G>A p.R441= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as rs964640304, COSV55314128; called by muse, mutect2
- RELN | c.4173G>A p.E1391= | Silent (SNP) | VAF 21/72 reads (29%) | catalogued as COSV100634403, COSV59005917; called by muse, mutect2, varscan2
- SCARF2 | c.2214C>T p.L738= | Silent (SNP) | VAF 7/13 reads (54%) | catalogued as COSV56732434; called by muse, mutect2
- SCN3A | c.5679C>T p.T1893= | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as COSV51811856; called by muse, mutect2, varscan2
- SCRN2 | c.1143G>A p.Q381= | Silent (SNP) | VAF 13/68 reads (19%) | catalogued as COSV51636062; called by muse, mutect2, varscan2
- SLC35F4 | c.1350G>T p.V450= (on ENST00000339762 / NM_001352015.2; = p.V414= on NM_001206920.1 and 1 other RefSeq transcript) | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as COSV60262973, COSV60265129; called by muse, mutect2
- SNAP91 | c.2358G>A p.E786= | Silent (SNP) | VAF 3/10 reads (30%) | catalogued as COSV99534695; called by muse, mutect2
- SYNJ2 | c.696C>T p.F232= | Silent (SNP) | VAF 9/46 reads (20%) | catalogued as rs778933903, COSV62895589; called by muse, mutect2, varscan2
- TMC1 | c.2238G>A p.K746= | Silent (SNP) | VAF 8/19 reads (42%) | catalogued as COSV52776679, COSV99920073; called by muse, mutect2, varscan2
- UNC45B | c.666G>A p.R222= | Silent (SNP) | VAF 14/59 reads (24%) | catalogued as COSV52096330; called by muse, mutect2, varscan2
- ZC3H4 | c.2802G>A p.E934= | Silent (SNP) | VAF 29/197 reads (15%) | catalogued as COSV53413368; called by muse, mutect2, varscan2
- ZNF229 | c.468C>T p.F156= | Silent (SNP) | VAF 27/71 reads (38%) | catalogued as COSV52162364; called by muse, mutect2, varscan2
- HERC2P3 | n.608G>A | RNA (SNP) | VAF 8/142 reads (6%) | called by muse, mutect2
- NACA | c.71-4093C>T | Intron (SNP) | VAF 16/50 reads (32%) | catalogued as COSV100771154; called by muse, mutect2, varscan2
- NBPF7 | n.754del | RNA (DEL) | VAF 11/116 reads (9%) | called by mutect2, pindel
- NMNAT2 | c.86-10925G>A | Intron (SNP) | VAF 24/90 reads (27%) | catalogued as COSV54273086; called by muse, mutect2, varscan2
- SNORD115-34 | n.55C>T | RNA (SNP) | VAF 106/349 reads (30%) | catalogued as rs777163079; called by muse, mutect2, varscan2
- SNORD115-44 | n.5C>T | RNA (SNP) | VAF 44/298 reads (15%) | called by muse, mutect2, varscan2
